Surgical pathology report (de-identified scan), TCGA case TCGA-28-1752, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1752-01A (Primary Tumor).

[page 1 of 4]
Department of Pathology & Laboratory
Medicine
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, LEFT FRONTAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, LEFT FRONTAL, BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- Tumor necrosis: 0%
- Tumor attributable cellularity: 70%

C. BRAIN, LEFT FRONTAL, NCI #2, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Tumor necrosis: 1%
- Tumor attributable cellularity: 90%

D. BRAIN, LEFT FRONTAL, NCI #3, EXCISION:

- Glioblastoma multiforme, WHO grade IV
- Tumor necrosis: 1%
- Tumor attributable cellularity: 90%

E. BRAIN, LEFT FRONTAL, NCI #4, BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Tumor necrosis: 1%
- Tumor attributable cellularity: 90%

F. BRAIN, LEFT FRONTAL, NCI #5, EXCISION:

- Glioblastoma multiforme, WHO grade IV
- Tumor necrosis: 5%
- Tumor attributable cellularity: 90%

G. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. [REDACTED] hence, the low 2% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Patient Case(s):

[page 2 of 4]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #:

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED] hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED] Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival [REDACTED] Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

Pelloski et al. 2006. Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. [REDACTED]

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case predicts a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with

HISTORY: Left frontal brain tumor

MICROSCOPIC:

Sections disclose necrotizing predominantly well circumscribed but focally diffusely infiltrating astrocytoma featuring striking ependymal-like differentiation with palisading of nuclei and presence of perinuclear pseudorosettes. The tumor is predominantly composed of elongate hyperchromatic nuclei, associated with numerous mitotic figures and showing readily discernible eosinophilic cytoplasm. In addition to ependymal differentiation there is a presence of gemistocytic cells infiltrating brain parenchyma. Additionally, areas of highly cellular tumor with neuroblastic-like differentiation are also discerned (PNET-like component). A focally conspicuous microvascular proliferation is detected. Abundant tumor necrosis, some of which showing palisading, is also seen.

IMMUNOSTAINS:

p53 (G9): majority of tumor nuclei are positive in more aggressive appearing foci
Synaptophysin (G9): focal weak positivity in more aggressive appearing foci
MGMT (G1): positive in up to 2% of tumor nuclei
PTEN (G1): loss (1+)
pMAPK (G1): 10% of tumor nuclei are positive and 30% of tumor cell cytoplasm is positive
Laminin beta 1 (8/411) (G1): up-regulated (2+ in endothelial cells)
Laminin beta 2 (9/421) (G1): down regulated (focal perinuclear dot-like staining in endothelial cells (1-2+))
Neurofilament (G2): discloses trapped axons

GROSS:

[page 3 of 4]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #:

A. LEFT FRONTAL [REDACTED]

Labeled with the patient's name, labeled "left frontal [REDACTED]", and received fresh for intraoperative consultation and subsequently fixed in formalin is a piece of light tan tissue measuring approximately 0.3 x 0.3 x 0.2 cm. Entirely submitted.

Slide key:

A1. Frozen section remnant - 1

A2. Remainder of specimen - 1

B. LEFT FRONTAL NCI #1

Labeled with the patient's name, labeled "left frontal NCI #1", and received fresh and subsequently fixed in formalin are two irregular pieces of soft gray-tan tissue measuring 1.5 x 0.9 x 0.5 cm in aggregate. Entirely submitted.

B1. 2

C. LEFT FRONTAL NCI #2

Labeled with the patient's name, labeled "left frontal NCI #2", and received in formalin is a piece of soft white-tan tissue measuring 1.4 x 1.2 x 0.4 cm. Entirely submitted.

C1. 1

D. LEFT FRONTAL NCI #3

Labeled with the patient's name, labeled "left frontal NCI #3", and received in formalin is a single piece of hemorrhagic yellow to tan tissue measuring about 1.1 x 1.2 x 0.5 cm. Entirely submitted.

D1. 1

E. LEFT FRONTAL NCI #4

Labeled with the patient's name, labeled "left frontal NCI #4", and received in formalin is a piece of piece of soft tan to yellowish hemorrhagic tissue measuring 1.5 x 1.0 x 0.4 cm. Entirely submitted.

E1. 1

F. LEFT FRONTAL NCI #5

Labeled with the patient's name, labeled "left frontal NCI #5", and received in formalin is a single piece of soft yellow-tan tissue measuring 1.7 x 1.1 x 0.5 cm. Entirely submitted.

F1. 1

G. LEFT FRONTAL PERMANENT

Labeled with the patient's name, labeled "left frontal permanent", and received in formalin are multiple fragments of necrotic and hemorrhagic soft tan tissue measuring an aggregate 4.5 x 4.5 x 4.0 cm. Entirely submitted.

G1-G14. 1

Gross dictated by [REDACTED]

OPERATIVE CALL

OPERATIVE CONSULTATION

SPECIMEN A. LEFT FRONTAL FS AND TP:

- Glioblastoma

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Department of Pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

[page 4 of 4]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

PATH #:

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

M.D. Electronically signed [REDACTED]

ADDENDUM [REDACTED]

FISH (FLUORESCENCE IN SITU HYBRIDIZATION) for EGFR

RESULTS:**Number of cells analyzed: 40****Ratio of EGFR/CEP: 41.0****Percentage of cells with ≥ 4 copies of EGFR: 100%****Amplification: YES****High Level of Polysomy: YES****INTERPRETATION:**

1. Samples are interpreted as Positive if:
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. When high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

REFERENCES
[REDACTED]

Source: NCI Genomic Data Commons file dcab8764-aca4-4223-aea8-e2733981afac (TCGA-28-1752.2DCFCD58-1196-4A7D-A242-EF7D01DCCD00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).